Gene-level copy-number profile of tumor specimen TCGA-86-8279-01A from TCGA case TCGA-86-8279, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.6 years (17,032 days).
Specimen TCGA-86-8279-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c6c514a7-b395-4c46-8e37-78beada75217.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8279-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1a5757d-02cd-4f86-afb3-e60157e72d78

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 16; copy number 2: 4,187; copy number 3: 17,177; copy number 4: 11,849; copy number 5: 10,490; copy number 6: 1,550; copy number 7: 2,166; copy number 8: 5,544; copy number 9: 4,184; copy number 10: 1,616; copy number 11: 356; copy number 12: 44; copy number 13: 44; copy number 14: 226; copy number 15: 107; copy number 16: 193; copy number 18: 6; copy number 20: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8279-01A-11D-2283-01): tumor purity 0.5, ploidy 5.48, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 14,531 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,774,669–248,919,946, 3,086 genes, copy number 9 (broad region; genes not listed).
- chr4:49,096–60,922,684, 892 genes, copy number 8–12 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10–11 (broad region; genes not listed).
- chr6:167,607–69,389,506, 1,587 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr7:70,972–63,176,019, 1,086 genes, copy number 7 (broad region; genes not listed).
- chr8:37,405,439–113,616,958, 1,192 genes, copy number 8–20 (broad region; genes not listed).
- chr10:111,787,233–117,196,654, 83 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:40,114,203–135,075,908, 2,426 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:57,216,794–59,130,875, 69 genes, copy number 7 (broad region; genes not listed).
- chr12:67,648,338–69,699,476, 57 genes, copy number 7–9 (within-gene range 4–9): DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr14:18,333,726–19,936,757, 82 genes, copy number 7 (broad region; genes not listed).
- chr14:34,416,687–36,679,362, 73 genes, copy number 8 (broad region; genes not listed).
- chr16:30,336,400–62,187,646, 709 genes, copy number 7–12 (broad region; genes not listed).
- chr16:62,596,372–72,225,144, 310 genes, copy number 10 (broad region; genes not listed).
- chr16:73,386,771–82,575,518, 196 genes, copy number 8–11 (broad region; genes not listed).
- chr16:82,688,931–82,844,757, 5 genes, copy number 10: MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P.
- chr16:85,676,198–86,199,720, 27 genes, copy number 9 (within-gene range 5–9): GINS2, C16orf74, AC018695.6, AC018695.9, MIR1910, AC018695.2, EMC8, RNU1-103P, AC018695.4, AC018695.3, COX4I1, AC018695.5, AC018695.1, AC018695.8, AC018695.7, IRF8, MIR6774, AC092723.5, LINC02132, AC092723.4, AC092723.1, AC092723.3, AC092723.2, AC135012.1, AC135012.2, AC135012.3, LINC01082.
- chr17:19,334,308–21,043,760, 105 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr17:78,991,716–83,095,122, 192 genes, copy number 7 (broad region; genes not listed).
- chr20:30,214,765–64,313,132, 899 genes, copy number 7–8 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
